Somatic mutation profile of cancer-model specimen HCM-BROD-0339-C43-85M (Adherent Cell Line, passage 12; aliquot HCM-BROD-0339-C43-85M-01D-A79C-36), derived from the metastatic tumor of HCMI case HCM-BROD-0339-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 36.3 years (13,251 days).
Specimen HCM-BROD-0339-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 12.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3fb028ee-9f73-4f71-be67-0628bdfe924e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0339-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0339-C43-10A-01D-A79C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6962f1ac-563d-4b6f-af52-9586f9f4cbcc

The open-access MAF lists 404 somatic variants for this specimen: 270 protein-altering or splice-affecting, 123 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 243, Silent 123, Nonsense Mutation 17, Intron 4, 3'UTR 3, Splice Region 3, Frame Shift Ins 2, In Frame Del 2, 5'UTR 2, Splice Site 2, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 148/271 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- TP53 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 248/249 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730881999, COSV52666031, COSV52675881, COSV52731113, COSV52828604; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AC092143.1 | c.1955C>T p.P652L | Missense Mutation (SNP) | VAF 577/578 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV104396250; called by muse, mutect2, varscan2
- ADCY8 | c.1246C>T p.L416F | Missense Mutation (SNP) | VAF 111/235 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53895961, COSV99654440; called by muse, mutect2, varscan2
- ADGRG3 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 295/295 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368211978; called by muse, mutect2, varscan2
- ADORA2A | c.34G>A p.V12M | Missense Mutation (SNP) | VAF 371/750 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.254); catalogued as rs1287369177, COSV58379373; called by muse, mutect2, varscan2
- ADORA2A | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 438/823 reads (53%) | SIFT tolerated (0.78); PolyPhen benign (0.091); catalogued as COSV58377927; called by muse, mutect2, varscan2
- ANKRD30B | c.3539C>T p.P1180L | Missense Mutation (SNP) | VAF 84/91 reads (92%) | SIFT tolerated (0.08); PolyPhen benign (0.041); catalogued as COSV100271401; called by muse, mutect2, varscan2
- ANO4 | c.383C>T p.S128F (on ENST00000392977 / NM_001286615.2; = p.S93F on NM_178826.4) | Missense Mutation (SNP) | VAF 189/189 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); catalogued as rs199936621, COSV100152378; called by muse, mutect2, varscan2
- ARMC4 | c.3055G>A p.D1019N | Missense Mutation (SNP) | VAF 199/199 reads (100%) | SIFT tolerated (0.3); PolyPhen benign (0.139); catalogued as COSV59456466, COSV59461306; called by muse, mutect2, varscan2
- ARMC4 | c.2773C>T p.P925S | Missense Mutation (SNP) | VAF 120/120 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.314); catalogued as COSV100536616; called by muse, mutect2, varscan2
- ARVCF | c.2593C>T p.P865S | Missense Mutation (SNP) | VAF 300/608 reads (49%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs762406853; called by muse, mutect2, varscan2
- ATXN1 | c.633_634insTAG p.H211_Q212ins* | Nonsense Mutation (INS) | VAF 240/832 reads (29%) | catalogued as COSV55207739, COSV55225816; called by pindel, varscan2
- B3GALT1 | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 204/378 reads (54%) | SIFT tolerated (0.67); PolyPhen benign (0.035); catalogued as rs866876110, COSV59909329; called by muse, mutect2, varscan2
- BICD1 | c.2036C>T p.S679F | Missense Mutation (SNP) | VAF 342/682 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV55688702; called by muse, mutect2, varscan2
- BRINP3 | c.1964C>T p.S655F | Missense Mutation (SNP) | VAF 555/555 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV66524819; called by muse, mutect2, varscan2
- BSN | c.6749G>A p.R2250Q | Missense Mutation (SNP) | VAF 394/394 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1299983273; called by muse, varscan2
- C11orf86 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 444/445 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as COSV100456973; called by muse, mutect2, varscan2
- C1orf56 | c.479G>A p.R160K | Missense Mutation (SNP) | VAF 860/866 reads (99%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1305196726; called by muse, mutect2, varscan2
- CACNA1F | c.5006C>T p.P1669L | Missense Mutation (SNP) | VAF 333/333 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV100544681; called by muse, mutect2, varscan2
- CACNA1H | c.2935G>A p.V979I | Missense Mutation (SNP) | VAF 295/296 reads (100%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.97); catalogued as rs759796507; called by muse, mutect2, varscan2
- CALCR | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 141/295 reads (48%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.458); catalogued as COSV64006005; called by muse, mutect2, varscan2
- CASP5 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 251/251 reads (100%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.836); catalogued as COSV52830397; called by muse, mutect2, varscan2
- CDH6 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 213/213 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54074005; called by muse, mutect2, varscan2
- CGNL1 | c.1006C>T p.P336S | Missense Mutation (SNP) | VAF 216/491 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs748559258, COSV55572722; called by muse, mutect2, varscan2
- CHD6 | c.4157C>T p.S1386L | Missense Mutation (SNP) | VAF 435/436 reads (100%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as rs764458413; called by muse, mutect2, varscan2
- COL1A1 | c.2386C>T p.R796C | Missense Mutation (SNP) | VAF 315/315 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs751890158, COSV56807243; called by muse, mutect2, varscan2
- COL22A1 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 255/543 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753523862, COSV57333838; called by muse, mutect2, varscan2
- COL28A1 | c.2189G>A p.G730D | Missense Mutation (SNP) | VAF 306/648 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.903); catalogued as rs373271322; called by muse, mutect2, varscan2
- COL2A1 | c.3023G>A p.G1008D | Missense Mutation (SNP) | VAF 296/547 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765795867, CD063499, COSV100477239; called by muse, mutect2, varscan2
- COL4A3 | c.2636C>T p.P879L | Missense Mutation (SNP) | VAF 90/191 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs368342782; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A4 | c.3707G>A p.G1236E | Missense Mutation (SNP) | VAF 128/245 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61632820; called by muse, mutect2, varscan2
- COL5A3 | c.3023C>A p.S1008Y | Missense Mutation (SNP) | VAF 298/298 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs781508162; called by muse, mutect2, varscan2
- CPA2 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 199/430 reads (46%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.68); catalogued as rs201088138; called by muse, mutect2, varscan2
- CSMD3 | c.1310G>A p.R437K | Missense Mutation (SNP) | VAF 166/333 reads (50%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.815); catalogued as rs566426423, COSV52109016, COSV52145907; called by muse, mutect2, varscan2
- CYP26C1 | c.1039G>A p.G347R | Missense Mutation (SNP) | VAF 462/462 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as rs1176947666; called by muse, mutect2, varscan2
- CYP26C1 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 458/458 reads (100%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs762204088; called by muse, mutect2, varscan2
- DDN | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 554/1181 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.273); catalogued as rs753561904; called by muse, mutect2, varscan2
- DDX4 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 433/433 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61754856; called by muse, mutect2, varscan2
- DMBT1 | c.2342C>T p.S781L | Missense Mutation (SNP) | VAF 384/384 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.165); catalogued as rs571730382, COSV57563473; called by muse, mutect2, varscan2
- DNAH3 | c.5209G>A p.E1737K | Missense Mutation (SNP) | VAF 218/218 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.11); catalogued as rs755641783; called by muse, mutect2, varscan2
- DNAH7 | c.2855G>A p.G952E | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs775319314; called by muse, mutect2, varscan2
- DYNC2H1 | c.12550C>T p.R4184C | Missense Mutation (SNP) | VAF 198/198 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767920377, COSV62086491; called by muse, mutect2, varscan2
- EMB | c.817C>T p.L273F | Missense Mutation (SNP) | VAF 348/352 reads (99%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); catalogued as COSV57480619; called by mutect2, varscan2
- ENPP6 | c.1009C>G p.P337A | Missense Mutation (SNP) | VAF 236/236 reads (100%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.908); catalogued as COSV99699179; called by muse, mutect2, varscan2
- EVC2 | c.1992G>T p.K664N | Missense Mutation (SNP) | VAF 218/219 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100185399; called by muse, mutect2, varscan2
- FAM135B | c.1817C>T p.S606F | Missense Mutation (SNP) | VAF 343/689 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV52719715, COSV99417311; called by muse, mutect2, varscan2
- FAN1 | c.2875C>T p.P959S | Missense Mutation (SNP) | VAF 294/554 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146600264; called by muse, mutect2, varscan2
- FSHR | c.1198C>T p.L400F | Missense Mutation (SNP) | VAF 134/294 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as rs765583608; called by muse, mutect2, varscan2
- GALNT2 | c.739C>T p.R247W | Missense Mutation (SNP) | VAF 406/406 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775177578, COSV64194107; called by muse, mutect2, varscan2
- GLI2 | c.3266G>A p.G1089D (on ENST00000361492 / NM_001374353.1; = p.G1106D on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 241/504 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs777267988, CM055283, COSV58050697; called by muse, mutect2, varscan2
- GLI3 | c.1337C>A p.P446Q | Missense Mutation (SNP) | VAF 207/458 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV101229893; called by muse, mutect2, varscan2
- GLYAT | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 261/261 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1413090557; called by muse, mutect2, varscan2
- GMPS | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 154/154 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV55811566; called by muse, mutect2, varscan2
- GOLGA6L6 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 326/404 reads (81%) | SIFT tolerated (0.44); PolyPhen benign (0.316); catalogued as rs749175278; called by muse, mutect2, varscan2
- GOLGA8R | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 56/378 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1468522175; called by muse, mutect2, varscan2
- GPR78 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 673/673 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.661); catalogued as rs1317676429; called by muse, mutect2, varscan2
- GRB7 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 335/336 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58446672; called by muse, mutect2, varscan2
- GRM7 | c.2452C>T p.L818F | Missense Mutation (SNP) | VAF 147/147 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.346); catalogued as COSV63136401; called by muse, mutect2, varscan2
- HAVCR2 | c.13C>T p.L5F | Missense Mutation (SNP) | VAF 32/452 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.22); catalogued as rs1372149834; called by muse, mutect2
- HCN1 | c.1618G>A p.E540K | Missense Mutation (SNP) | VAF 179/179 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100299579; called by muse, mutect2, varscan2
- HTR2A | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 389/835 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.025); catalogued as rs778682687, COSV101096643, COSV99059994; called by muse, mutect2, varscan2
- IFNA6 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 179/179 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1181102432, COSV66506695; called by muse, mutect2, varscan2
- KAT6B | c.1717C>T p.R573C | Missense Mutation (SNP) | VAF 257/257 reads (100%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.549); catalogued as rs756038238, COSV54742537; called by muse, mutect2, varscan2
- KATNB1 | c.698C>T p.P233L | Missense Mutation (SNP) | VAF 390/391 reads (100%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.492); catalogued as rs782579971; called by muse, mutect2, varscan2
- KIAA0232 | c.1280G>A p.R427K | Missense Mutation (SNP) | VAF 238/239 reads (100%) | SIFT tolerated (0.43); PolyPhen benign (0.006); catalogued as COSV56923345; called by muse, mutect2, varscan2
- KLF14 | c.232G>A p.G78S | Missense Mutation (SNP) | VAF 484/1025 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as rs1342956484; called by muse, mutect2, varscan2
- KMT2C | c.6016C>T p.H2006Y | Missense Mutation (SNP) | VAF 231/454 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as COSV51427466; called by muse, mutect2, varscan2
- LOXL3 | c.1208G>A p.G403E | Missense Mutation (SNP) | VAF 163/329 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs1290840534, COSV99239844; called by muse, mutect2, varscan2
- LRATD1 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 228/510 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.143); catalogued as COSV99707314; called by muse, mutect2, varscan2
- LRIF1 | c.1361C>T p.T454I | Missense Mutation (SNP) | VAF 153/153 reads (100%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV100870950; called by muse, mutect2, varscan2
- MAGEC2 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 403/404 reads (100%) | SIFT tolerated (0.51); PolyPhen benign (0.024); catalogued as COSV56001522; called by muse, mutect2, varscan2
- MAP7D2 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 222/222 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV101107525; called by muse, mutect2, varscan2
- MET | c.2873G>A p.R958K | Missense Mutation (SNP) | VAF 110/224 reads (49%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV59268688; called by muse, mutect2, varscan2
- METTL2A | c.1042C>T p.R348C | Missense Mutation (SNP) | VAF 405/413 reads (98%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as rs988722853; called by muse, mutect2, varscan2
- MGA | c.7396C>T p.R2466* (on ENST00000219905 / NM_001164273.1; = p.R2257* on NM_001080541.2) | Nonsense Mutation (SNP) | VAF 106/225 reads (47%) | catalogued as COSV54950944; called by muse, mutect2, varscan2
- MROH2A | c.862G>A p.G288S | Missense Mutation (SNP) | VAF 139/320 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752653076; called by muse, mutect2, varscan2
- MUC16 | c.41624G>A p.R13875K | Missense Mutation (SNP) | VAF 300/301 reads (100%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.841); catalogued as COSV66696243; called by muse, mutect2, varscan2
- MUC16 | c.24874G>A p.A8292T | Missense Mutation (SNP) | VAF 262/264 reads (99%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.01); catalogued as rs778216388, COSV67443869; called by muse, mutect2, varscan2
- MUC16 | c.18389C>T p.S6130F | Missense Mutation (SNP) | VAF 337/339 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); catalogued as rs780590119; called by muse, mutect2, varscan2
- MYH10 | c.2384C>T p.A795V | Missense Mutation (SNP) | VAF 212/212 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV52609854; called by muse, mutect2, varscan2
- NCOR1 | c.6848G>A p.G2283E | Missense Mutation (SNP) | VAF 269/269 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV51981993, COSV99252735; called by muse, mutect2, varscan2
- NIF3L1 | c.807A>G p.I269M (on ENST00000409020 / NM_001369444.1; = p.I242M on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 150/294 reads (51%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.844); catalogued as COSV62899968; called by muse, mutect2, varscan2
- NLRP12 | c.1240C>T p.L414F | Missense Mutation (SNP) | VAF 392/393 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747186204; called by muse, mutect2, varscan2
- NLRP3 | c.1873C>T p.Q625* | Nonsense Mutation (SNP) | VAF 586/589 reads (99%) | catalogued as COSV60231908; called by muse, mutect2, varscan2
- NLRP5 | c.2284G>A p.D762N | Missense Mutation (SNP) | VAF 224/224 reads (100%) | SIFT tolerated (0.55); PolyPhen benign (0.03); catalogued as rs1361699751, COSV66766154; called by muse, mutect2, varscan2
- NRK | c.1561C>T p.Q521* | Nonsense Mutation (SNP) | VAF 439/441 reads (100%) | catalogued as COSV54600407; called by muse, mutect2, varscan2
- OR51E1 | c.920G>A p.R307Q | Missense Mutation (SNP) | VAF 210/210 reads (100%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs751394816, COSV67809975; called by muse, mutect2, varscan2
- OTOF | c.1834C>T p.L612F | Missense Mutation (SNP) | VAF 194/402 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV55518978; called by muse, mutect2, varscan2
- P2RX4 | c.149G>A p.W50* | Nonsense Mutation (SNP) | VAF 205/205 reads (100%) | catalogued as rs767702661; called by muse, mutect2, varscan2
- PAXIP1 | c.604G>T p.E202* | Nonsense Mutation (SNP) | VAF 245/587 reads (42%) | catalogued as COSV68188023; called by muse, mutect2, varscan2
- PCDHGA1 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 238/239 reads (100%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.001); catalogued as rs866306738, COSV65296140; called by muse, mutect2, varscan2
- PCLO | c.7237C>T p.P2413S | Missense Mutation (SNP) | VAF 78/158 reads (49%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.165); catalogued as rs1310852371; called by muse, mutect2, varscan2
- PDE4DIP | c.6110A>G p.Q2037R | Missense Mutation (SNP) | VAF 248/283 reads (88%) | SIFT tolerated (0.42); PolyPhen benign (0.04); catalogued as rs1559410614; called by muse, mutect2, varscan2
- PEAK1 | c.4823C>T p.P1608L | Missense Mutation (SNP) | VAF 285/628 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56942992; called by muse, mutect2, varscan2
- PKHD1L1 | c.3836G>A p.G1279E | Missense Mutation (SNP) | VAF 171/414 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.175); catalogued as rs867986792, COSV65741514; called by muse, mutect2, varscan2
- PLEKHB2 | c.739C>T p.P247S | Missense Mutation (SNP) | VAF 69/173 reads (40%) | PolyPhen benign (0); catalogued as rs1198196072; called by muse, varscan2
- PLEKHH1 | c.2047C>T p.R683W | Missense Mutation (SNP) | VAF 362/362 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs775323773, COSV61284006, COSV61288809; called by muse, mutect2, varscan2
- PLEKHH3 | c.1463C>T p.S488F | Missense Mutation (SNP) | VAF 394/394 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as rs1227815984; called by muse, mutect2, varscan2
- PLIN2 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 176/176 reads (100%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.811); catalogued as rs1182340269; called by muse, mutect2, varscan2
- POM121L12 | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 514/1088 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs766446464, COSV68693059, COSV68694334; called by muse, varscan2
- PREX2 | c.2114G>A p.G705E | Missense Mutation (SNP) | VAF 161/292 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1213028913, COSV55766250; called by muse, mutect2, varscan2
- PRR14L | c.645C>A p.H215Q | Missense Mutation (SNP) | VAF 42/604 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs1376965192, COSV57888507; called by muse, mutect2
- PSG8 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 182/182 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs142736244; called by muse, mutect2, varscan2
- PTPRD | c.2878G>A p.D960N | Missense Mutation (SNP) | VAF 358/358 reads (100%) | SIFT tolerated (0.05); PolyPhen benign (0.081); catalogued as rs1381492310, COSV61989344; called by muse, mutect2, varscan2
- PXDN | c.2294G>A p.R765H | Missense Mutation (SNP) | VAF 211/433 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV53234044; called by muse, mutect2, varscan2
- RAD54L | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 287/287 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1449828957; called by muse, mutect2, varscan2
- RASIP1 | c.1025G>A p.R342Q | Missense Mutation (SNP) | VAF 669/670 reads (100%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as rs746117962; called by muse, mutect2, varscan2
- RELN | c.6470C>T p.P2157L | Missense Mutation (SNP) | VAF 255/531 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs1412766990; called by muse, mutect2, varscan2
- RNASE12 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 268/268 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV100250459, COSV60087590; called by muse, mutect2, varscan2
- RSAD2 | c.568C>T p.L190F | Missense Mutation (SNP) | VAF 116/225 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.888); catalogued as COSV101149912; called by muse, mutect2, varscan2
- SAMD7 | c.106G>A p.V36I | Missense Mutation (SNP) | VAF 190/192 reads (99%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs772594842, COSV100157064, COSV59420723; called by muse, varscan2
- SAMHD1 | c.346A>C p.K116Q | Missense Mutation (SNP) | VAF 341/341 reads (100%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.659); catalogued as COSV99484010; called by muse, mutect2, varscan2
- SCN1A | c.1838G>A p.R613Q | Missense Mutation (SNP) | VAF 174/371 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.585); catalogued as rs755323236; called by muse, mutect2, varscan2
- SDC3 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 503/505 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1466152141; called by muse, mutect2, varscan2
- SELP | c.1396G>C p.G466R | Missense Mutation (SNP) | VAF 606/606 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs753794052; called by muse, mutect2, varscan2
- SEPTIN3 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 349/774 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs1162204321; called by muse, mutect2, varscan2
- SERHL2 | c.614-1G>A p.X205_splice | Splice Site (SNP) | VAF 213/478 reads (45%) | catalogued as COSV59669815; called by muse, mutect2, varscan2
- SERHL2 | c.614G>A p.G205D | Missense Mutation (SNP) | VAF 215/480 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs763405033; called by muse, mutect2, varscan2
- SLCO2A1 | c.1897G>A p.E633K | Missense Mutation (SNP) | VAF 305/306 reads (100%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs1181672885, COSV100188632; called by muse, mutect2, varscan2
- TACC1 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 294/605 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs201280385; called by muse, mutect2, varscan2
- TBX18 | c.1655G>A p.G552E | Missense Mutation (SNP) | VAF 312/313 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.291); catalogued as COSV63737494, COSV63738579; called by muse, mutect2, varscan2
- THSD7B | c.2773G>A p.E925K | Missense Mutation (SNP) | VAF 153/280 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV55654466; called by muse, mutect2, varscan2
- TIAM2 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 242/242 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.949); catalogued as rs201514936; called by muse, mutect2, varscan2
- TICRR | c.4649C>T p.S1550F | Missense Mutation (SNP) | VAF 289/527 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.858); catalogued as COSV51543903; called by muse, mutect2, varscan2
- TLR2 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 272/272 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52605815; called by muse, mutect2, varscan2
- TRBV19 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 134/360 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs1459424317; called by muse, mutect2, varscan2
- TRIM33 | c.2941G>A p.E981K | Missense Mutation (SNP) | VAF 174/174 reads (100%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.675); catalogued as COSV100635188; called by muse, mutect2, varscan2
- TSPYL5 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 613/1301 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1472423885; called by muse, mutect2, varscan2
- TTN | c.82030G>A p.G27344R (on ENST00000591111; = p.G19920R on NM_003319.4) | Missense Mutation (SNP) | VAF 145/354 reads (41%) | PolyPhen probably damaging (1); catalogued as rs748946057, COSV100605094, COSV59901297; called by muse, mutect2, varscan2
- TTN | c.71129G>A p.W23710* (on ENST00000591111; = p.W16286* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 152/280 reads (54%) | catalogued as COSV60258811; called by muse, mutect2, varscan2
- TTN | c.42916G>A p.E14306K (on ENST00000591111; = p.E6882K on NM_003319.4) | Missense Mutation (SNP) | VAF 64/147 reads (44%) | PolyPhen benign (0.053); catalogued as rs1240010379, COSV59922255; called by muse, mutect2, varscan2
- TTN | c.28447G>A p.D9483N (on ENST00000591111; = p.D8556N on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 94/200 reads (47%) | PolyPhen benign (0.118); catalogued as COSV60244303; called by muse, mutect2, varscan2
- TUBB8 | c.165C>T p.S55= | Splice Region (SNP) | VAF 50/492 reads (10%) | catalogued as rs1554738859, COSV59118011; called by muse, mutect2
- ZAN | c.7346G>A p.R2449K | Missense Mutation (SNP) | VAF 255/532 reads (48%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs1287281798; called by muse, mutect2
- ZNF106 | c.14G>A p.R5Q | Missense Mutation (SNP) | VAF 147/368 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as rs1345782972; called by muse, mutect2, varscan2
- ZNF318 | c.4741C>T p.P1581S | Missense Mutation (SNP) | VAF 363/365 reads (99%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.007); catalogued as rs57667731; called by muse, mutect2, varscan2
- ZNF461 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 283/283 reads (100%) | SIFT tolerated (0.12); PolyPhen benign (0.07); catalogued as rs780052934; called by muse, mutect2, varscan2
- ZNF680 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 109/252 reads (43%) | catalogued as COSV59015187; called by muse, mutect2, varscan2
- ZP1 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 488/488 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); catalogued as COSV53925007; called by muse, mutect2, varscan2
- ABCA10 | c.1030C>T p.P344S | Missense Mutation (SNP) | VAF 118/118 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- ABCF2 | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 215/480 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- ABHD16B | c.323G>A p.R108H | Missense Mutation (SNP) | VAF 259/1189 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ACBD4 | c.530C>T p.S177F | Missense Mutation (SNP) | VAF 290/291 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ADRA2A | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 169/409 reads (41%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- AFDN | c.3052A>T p.M1018L | Missense Mutation (SNP) | VAF 185/185 reads (100%) | SIFT tolerated (0.16); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- AMY2B | c.1213C>T p.Q405* | Nonsense Mutation (SNP) | VAF 184/198 reads (93%) | called by muse, mutect2, varscan2
- ARFGEF3 | c.5654C>T p.P1885L | Missense Mutation (SNP) | VAF 366/366 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- ARVCF | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 350/667 reads (52%) | SIFT tolerated (0.7); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- BDKRB1 | c.757C>A p.L253I | Missense Mutation (SNP) | VAF 487/487 reads (100%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- BRD4 | c.2342C>T p.P781L | Missense Mutation (SNP) | VAF 187/187 reads (100%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- BTNL3 | c.344G>A p.W115* | Nonsense Mutation (SNP) | VAF 524/524 reads (100%) | called by muse, mutect2, varscan2
- C1QTNF9B | c.427G>T p.G143W | Missense Mutation (SNP) | VAF 639/1294 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- CALCOCO1 | c.416T>C p.I139T | Missense Mutation (SNP) | VAF 319/320 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- CALCRL | c.881T>C p.I294T | Missense Mutation (SNP) | VAF 119/225 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- CBLIF | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 259/259 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- CDHR2 | c.3022C>T p.L1008F | Missense Mutation (SNP) | VAF 420/420 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDKL4 | c.953G>A p.R318K | Missense Mutation (SNP) | VAF 136/261 reads (52%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFAP20DC | c.1867del p.I623Sfs*15 | Frame Shift Del (DEL) | VAF 314/438 reads (72%) | called by mutect2, pindel, varscan2
- CLCNKA | c.1639G>T p.V547L | Missense Mutation (SNP) | VAF 345/351 reads (98%) | SIFT tolerated (0.05); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- CLSTN3 | c.1697_1698+2delinsGAA p.X566_splice | Splice Site (DEL) | VAF 142/143 reads (99%) | called by pindel, varscan2*
- CNKSR1 | c.1669C>T p.P557S (on ENST00000374253 / NM_001297647.2; = p.P550S on NM_006314.3) | Missense Mutation (SNP) | VAF 575/575 reads (100%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- CNKSR1 | c.1670C>T p.P557L (on ENST00000374253 / NM_001297647.2; = p.P550L on NM_006314.3) | Missense Mutation (SNP) | VAF 574/574 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- COCH | c.1462G>A p.D488N (on ENST00000216361 / NM_001347720.1; = p.D423N on NM_004086.3) | Missense Mutation (SNP) | VAF 233/233 reads (100%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- COL28A1 | c.1769T>C p.I590T | Missense Mutation (SNP) | VAF 257/593 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- COL4A5 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 213/213 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- COL6A1 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 293/294 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- CTAGE4 | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 142/538 reads (26%) | called by muse, mutect2, varscan2
- DMRT3 | c.1415C>T p.S472F | Missense Mutation (SNP) | VAF 187/187 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH6 | c.10294C>T p.H3432Y | Missense Mutation (SNP) | VAF 151/309 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DSCAML1 | c.5032G>A p.E1678K (on ENST00000321322; = p.E1618K on NM_020693.4) | Missense Mutation (SNP) | VAF 279/279 reads (100%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DUOX1 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 135/347 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- DUOX1 | c.1393C>A p.L465M | Missense Mutation (SNP) | VAF 159/305 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- EEF1A2 | c.267C>G p.I89M | Missense Mutation (SNP) | VAF 437/847 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- EFR3B | c.1216C>T p.P406S | Missense Mutation (SNP) | VAF 182/411 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EMCN | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 151/152 reads (99%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ENKUR | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 80/80 reads (100%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPB41L1 | c.2209G>A p.G737R | Missense Mutation (SNP) | VAF 550/550 reads (100%) | SIFT tolerated (0.33); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ERBB3 | c.3258_3275del p.M1087_L1092del | In Frame Del (DEL) | VAF 216/223 reads (97%) | called by mutect2, pindel, varscan2
- ERICH6B | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 857/859 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- EXOC4 | c.2564G>A p.G855D | Missense Mutation (SNP) | VAF 224/525 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- F8 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 353/353 reads (100%) | SIFT tolerated (0.35); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FAIM2 | c.551G>T p.G184V | Missense Mutation (SNP) | VAF 287/287 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- FBRS | c.301C>T p.Q101* (on ENST00000287468; = p.Q621* on NM_001105079.3) | Nonsense Mutation (SNP) | VAF 326/326 reads (100%) | called by muse, mutect2, varscan2
- FHL5 | c.290A>G p.E97G | Missense Mutation (SNP) | VAF 312/312 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- FIGNL1 | c.1631C>G p.A544G | Missense Mutation (SNP) | VAF 218/459 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FNIP1 | c.2601dup p.E868Rfs*11 | Frame Shift Ins (INS) | VAF 215/299 reads (72%) | called by mutect2, pindel, varscan2
- GALNT5 | c.1054G>A p.G352S | Missense Mutation (SNP) | VAF 84/180 reads (47%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- GOLGA8K | c.656T>C p.L219P | Missense Mutation (SNP) | VAF 65/206 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by mutect2, varscan2
- GULP1 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 61/155 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- H1-4 | c.435_485del p.T146_A162del | In Frame Del (DEL) | VAF 274/938 reads (29%) | called by mutect2, pindel
- HR | c.3205C>T p.L1069F | Missense Mutation (SNP) | VAF 314/314 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HTATSF1 | c.800T>G p.I267S | Missense Mutation (SNP) | VAF 251/251 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- IGKV2-30 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 114/235 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- IGKV2-30 | c.47C>A p.P16Q | Missense Mutation (SNP) | VAF 90/251 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.282); called by muse, varscan2
- JMJD7-PLA2G4B | c.1688C>T p.T563I | Missense Mutation (SNP) | VAF 297/574 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNK13 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 318/318 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KNL1 | c.2780C>G p.T927S (on ENST00000346991 / NM_170589.5; = p.T901S on NM_144508.5) | Missense Mutation (SNP) | VAF 123/258 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRRK2 | c.5395G>T p.D1799Y | Missense Mutation (SNP) | VAF 153/345 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- MBD5 | c.4469G>A p.R1490K | Missense Mutation (SNP) | VAF 102/222 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MEFV | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 317/317 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MGAM2 | c.5692C>T p.P1898S | Missense Mutation (SNP) | VAF 259/550 reads (47%) | SIFT deleterious, low confidence (0.03); called by muse, mutect2, varscan2
- MORN1 | c.887C>T p.P296L | Missense Mutation (SNP) | VAF 355/355 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MYH9 | c.3904G>A p.D1302N | Missense Mutation (SNP) | VAF 322/662 reads (49%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- MYH9 | c.2945T>G p.I982S | Missense Mutation (SNP) | VAF 375/846 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MYO15B | c.8468C>G p.P2823R | Missense Mutation (SNP) | VAF 360/362 reads (99%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- MYO1H | c.86T>C p.V29A | Missense Mutation (SNP) | VAF 401/401 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYO9A | c.6967G>A p.E2323K | Missense Mutation (SNP) | VAF 237/544 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- MYPN | c.204C>G p.S68R | Missense Mutation (SNP) | VAF 246/246 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- NANOGP8 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 238/569 reads (42%) | called by muse, mutect2, varscan2
- NFXL1 | c.1910T>A p.I637N | Missense Mutation (SNP) | VAF 124/124 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- NLRC5 | c.2625G>A p.V875= | Splice Region (SNP) | VAF 217/217 reads (100%) | called by muse, mutect2, varscan2
- NUDT13 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 168/168 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- NUTM2B | c.1256C>T p.S419L | Missense Mutation (SNP) | VAF 87/243 reads (36%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR10Z1 | c.413C>T p.P138L | Missense Mutation (SNP) | VAF 657/658 reads (100%) | SIFT tolerated (0.65); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- OR4C16 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 277/277 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- OR4D6 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 260/260 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- PAX4 | c.145-7G>A | Splice Region (SNP) | VAF 394/835 reads (47%) | called by muse, mutect2, varscan2
- PCDHB2 | c.1409T>C p.L470P | Missense Mutation (SNP) | VAF 920/1482 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- PCDHB8 | c.194T>C p.V65A | Missense Mutation (SNP) | VAF 182/2622 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2
- PLCG2 | c.1937G>A p.W646* | Nonsense Mutation (SNP) | VAF 256/256 reads (100%) | called by muse, mutect2, varscan2
- POF1B | c.533C>T p.T178I | Missense Mutation (SNP) | VAF 89/89 reads (100%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- POU3F1 | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 719/721 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PPIP5K1 | c.865A>C p.K289Q | Missense Mutation (SNP) | VAF 114/933 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- PRR12 | c.1378T>G p.F460V (on ENST00000615927; = p.F1281V on NM_020719.3) | Missense Mutation (SNP) | VAF 467/467 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PRUNE2 | c.8242C>T p.L2748F | Missense Mutation (SNP) | VAF 219/221 reads (99%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PTPN13 | c.2336A>C p.H779P | Missense Mutation (SNP) | VAF 215/215 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBP3 | c.2010G>T p.Q670H | Missense Mutation (SNP) | VAF 310/310 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- RERE | c.2927C>T p.S976F | Missense Mutation (SNP) | VAF 365/368 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- RGS7 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 215/215 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RGS9 | c.1682T>G p.L561R | Missense Mutation (SNP) | VAF 470/470 reads (100%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- RHAG | c.899G>T p.G300V | Missense Mutation (SNP) | VAF 229/230 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNF31 | c.136G>C p.A46P | Missense Mutation (SNP) | VAF 455/455 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, varscan2
- RYR1 | c.8560G>A p.G2854S | Missense Mutation (SNP) | VAF 296/297 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SEC14L1 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 382/382 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SFXN2 | c.850G>A p.G284R | Missense Mutation (SNP) | VAF 243/243 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- SH3PXD2A | c.2432C>T p.P811L (on ENST00000369774 / NM_001365079.1; = p.P783L on NM_014631.2) | Missense Mutation (SNP) | VAF 332/332 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- SH3RF3 | c.2243C>T p.P748L | Missense Mutation (SNP) | VAF 216/452 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- SLC5A12 | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 95/202 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMAD1 | c.197C>A p.T66N | Missense Mutation (SNP) | VAF 361/362 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SMARCA5 | c.3080G>A p.G1027E | Missense Mutation (SNP) | VAF 76/76 reads (100%) | SIFT tolerated (0.09); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- SP140L | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- SPOCD1 | c.1321A>G p.S441G | Missense Mutation (SNP) | VAF 674/674 reads (100%) | SIFT tolerated (0.35); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- SPRYD3 | c.1154G>A p.G385E | Missense Mutation (SNP) | VAF 458/458 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D15 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 162/162 reads (100%) | SIFT tolerated (0.3); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- TEX43 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 231/232 reads (100%) | SIFT tolerated (0.23); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- THOC1 | c.836C>T p.T279I | Missense Mutation (SNP) | VAF 126/126 reads (100%) | SIFT tolerated (0.57); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TKTL2 | c.737C>A p.T246N | Missense Mutation (SNP) | VAF 321/321 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM201 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 485/486 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- TNFRSF8 | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 515/516 reads (100%) | SIFT tolerated (0.22); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- TPH1 | c.1223T>A p.I408N | Missense Mutation (SNP) | VAF 249/249 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- TRABD2A | c.821C>T p.P274L (on ENST00000409520 / NM_001277053.2; = p.P225L on NM_001080824.3) | Missense Mutation (SNP) | VAF 87/183 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- TRAPPC9 | c.2489C>T p.P830L | Missense Mutation (SNP) | VAF 216/499 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- TRIM43B | c.463C>T p.Q155* | Nonsense Mutation (SNP) | VAF 62/143 reads (43%) | called by muse, mutect2, varscan2
- TRIM47 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 456/457 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TRIM77 | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 186/186 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- TSPAN10 | c.457_458insT p.P153Lfs*31 (on ENST00000574882 / NM_001290212.1; = p.P115Lfs*31 on NM_031945.4) | Frame Shift Ins (INS) | VAF 442/544 reads (81%) | called by mutect2, pindel
- TTLL6 | c.2552C>T p.P851L (on ENST00000393382 / NM_001130918.3; = p.P544L on NM_173623.3) | Missense Mutation (SNP) | VAF 326/328 reads (99%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); called by muse, varscan2
- TTLL9 | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 171/416 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TXN2 | c.72G>A p.W24* | Nonsense Mutation (SNP) | VAF 314/607 reads (52%) | called by muse, varscan2
- TYW3 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 188/188 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDPCP | c.1642C>T p.L548F | Missense Mutation (SNP) | VAF 83/181 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- WHAMM | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 142/256 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- WNT6 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 340/669 reads (51%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- ZC3HAV1 | c.2249C>T p.S750F | Missense Mutation (SNP) | VAF 171/333 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZFHX3 | c.1888G>A p.G630R | Missense Mutation (SNP) | VAF 446/447 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ZNF180 | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 150/150 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF287 | c.1159C>T p.Q387* | Nonsense Mutation (SNP) | VAF 246/246 reads (100%) | called by muse, mutect2, varscan2
- ZNF544 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 267/268 reads (100%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZSWIM5 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 532/532 reads (100%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCF2 | c.390T>C p.A130= | Silent (SNP) | VAF 206/424 reads (49%) | called by muse, varscan2
- ACSS3 | c.534C>T p.I178= | Silent (SNP) | VAF 246/246 reads (100%) | catalogued as rs764965164; called by muse, mutect2, varscan2
- ADA2 | c.654C>T p.I218= | Silent (SNP) | VAF 286/574 reads (50%) | called by muse, varscan2
- ADGRL3 | c.822G>T p.V274= (on ENST00000506720 / NM_001322402.2; = p.V206= on NM_015236.6) | Silent (SNP) | VAF 277/277 reads (100%) | called by muse, mutect2, varscan2
- AL160272.2 | c.108C>T p.L36= | Silent (SNP) | VAF 170/170 reads (100%) | called by muse, mutect2, varscan2
- ANGPT1 | c.678A>G p.Q226= | Silent (SNP) | VAF 229/474 reads (48%) | called by muse, mutect2, varscan2
- ANKRD13B | c.1194G>A p.A398= | Silent (SNP) | VAF 353/353 reads (100%) | catalogued as rs776199636, COSV61472472; called by muse, mutect2, varscan2
- ANO4 | c.384C>T p.S128= (on ENST00000392977 / NM_001286615.2; = p.S93= on NM_178826.4) | Silent (SNP) | VAF 190/190 reads (100%) | called by muse, mutect2, varscan2
- AP4B1 | c.438G>A p.K146= | Silent (SNP) | VAF 207/207 reads (100%) | called by muse, mutect2, varscan2
- APBB1IP | c.312C>T p.F104= | Silent (SNP) | VAF 341/341 reads (100%) | catalogued as rs894488051; called by muse, mutect2, varscan2
- APOBR | c.2319G>A p.L773= (on ENST00000431282; = p.L782= on NM_018690.4) | Silent (SNP) | VAF 336/336 reads (100%) | called by muse, mutect2, varscan2
- ARAP1 | c.1764G>T p.R588= (on ENST00000393609 / NM_001040118.2; = p.R343= on NM_015242.4) | Silent (SNP) | VAF 512/513 reads (100%) | called by muse, mutect2, varscan2
- ARHGAP28 | c.576G>A p.Q192= (on ENST00000383472 / NM_001366230.1; = p.Q33= on NM_001010000.3) | Silent (SNP) | VAF 309/309 reads (100%) | catalogued as COSV51643706; called by muse, mutect2, varscan2
- ARSD | c.1606C>T p.L536= | Silent (SNP) | VAF 484/485 reads (100%) | called by muse, mutect2, varscan2
- ASPHD1 | c.522C>T p.G174= | Silent (SNP) | VAF 407/409 reads (100%) | called by muse, mutect2, varscan2
- ATP8B3 | c.1389C>T p.D463= | Silent (SNP) | VAF 44/400 reads (11%) | catalogued as rs753667949; called by muse, mutect2, varscan2
- C20orf194 | c.634C>T p.L212= | Silent (SNP) | VAF 186/360 reads (52%) | catalogued as rs763557076; called by muse, mutect2, varscan2
- CASP5 | c.223C>T p.L75= | Silent (SNP) | VAF 166/166 reads (100%) | catalogued as rs1249901937; called by muse, mutect2, varscan2
- CDHR2 | c.3021C>T p.S1007= | Silent (SNP) | VAF 420/420 reads (100%) | called by muse, mutect2, varscan2
- CENPE | c.4551C>T p.I1517= | Silent (SNP) | VAF 98/98 reads (100%) | called by muse, mutect2, varscan2
- CEP250 | c.6171G>A p.R2057= | Silent (SNP) | VAF 321/689 reads (47%) | catalogued as COSV100698916; called by muse, mutect2, varscan2
- CNGA3 | c.1671G>A p.G557= | Silent (SNP) | VAF 164/332 reads (49%) | called by muse, mutect2, varscan2
- COL4A2 | c.348C>T p.A116= | Silent (SNP) | VAF 211/452 reads (47%) | catalogued as rs1223427718, COSV100847372, COSV64626264; called by muse, mutect2, varscan2
- COL6A1 | c.1092C>A p.P364= | Silent (SNP) | VAF 285/287 reads (99%) | catalogued as COSV62613319; called by muse, mutect2, varscan2
- COLEC11 | c.606C>T p.F202= | Silent (SNP) | VAF 262/540 reads (49%) | called by muse, mutect2, varscan2
- CROCC | c.1569G>A p.L523= | Silent (SNP) | VAF 521/524 reads (99%) | catalogued as rs763218957; called by muse, mutect2, varscan2
- CSMD3 | c.7050C>T p.I2350= (on ENST00000297405 / NM_001363185.1; = p.I2246= on NM_052900.3) | Silent (SNP) | VAF 184/436 reads (42%) | catalogued as rs142588028, COSV99846430; called by muse, mutect2, varscan2
- DCDC2C | c.495C>T p.I165= | Silent (SNP) | VAF 88/185 reads (48%) | catalogued as rs1417282082, COSV70977352; called by muse, mutect2, varscan2
- EBI3 | c.567C>T p.I189= | Silent (SNP) | VAF 273/273 reads (100%) | called by muse, mutect2, varscan2
- EHD3 | c.966C>T p.F322= | Silent (SNP) | VAF 109/243 reads (45%) | catalogued as rs772720205, COSV100434636, COSV59029287; called by muse, mutect2, varscan2
- ELFN2 | c.1002C>T p.S334= | Silent (SNP) | VAF 322/722 reads (45%) | catalogued as rs138546342; called by muse, mutect2
- EP400 | c.603C>T p.I201= | Silent (SNP) | VAF 255/332 reads (77%) | catalogued as rs575382887; ClinVar: likely benign; called by muse, mutect2, varscan2
- EPHB6 | c.1950C>T p.S650= | Silent (SNP) | VAF 246/574 reads (43%) | catalogued as rs765773475, COSV100844402; called by muse, mutect2, varscan2
- ERVV-1 | c.21C>T p.F7= | Silent (SNP) | VAF 104/225 reads (46%) | catalogued as rs1301890726; called by muse, mutect2, varscan2
- FAM171A1 | c.1170G>A p.T390= | Silent (SNP) | VAF 292/292 reads (100%) | catalogued as rs771844084, COSV65313645; called by muse, mutect2, varscan2
- FARP2 | c.2595A>T p.P865= | Silent (SNP) | VAF 160/161 reads (99%) | called by muse, mutect2, varscan2
- FASN | c.2829C>T p.A943= | Silent (SNP) | VAF 286/287 reads (100%) | called by muse, mutect2, varscan2
- FCGR3A | c.156C>T p.S52= | Silent (SNP) | VAF 88/1150 reads (8%) | catalogued as COSV100914602; called by muse, mutect2
- FCGR3B | c.156C>T p.S52= | Silent (SNP) | VAF 712/713 reads (100%) | catalogued as COSV99670366; called by muse, mutect2
- FGA | c.702C>T p.P234= | Silent (SNP) | VAF 265/265 reads (100%) | catalogued as rs774638560, COSV57395360; called by muse, mutect2, varscan2
- GIMAP8 | c.762G>A p.G254= | Silent (SNP) | VAF 331/684 reads (48%) | catalogued as COSV56231526; called by muse, mutect2, varscan2
- GLIS3 | c.1770G>A p.G590= | Silent (SNP) | VAF 331/332 reads (100%) | catalogued as rs758580169; called by muse, mutect2, varscan2
- GPX5 | c.579C>T p.I193= | Silent (SNP) | VAF 644/1116 reads (58%) | called by muse, mutect2, varscan2
- GRIK3 | c.426G>C p.L142= | Silent (SNP) | VAF 459/460 reads (100%) | called by muse, mutect2, varscan2
- HBD | c.141G>A p.G47= | Silent (SNP) | VAF 287/287 reads (100%) | catalogued as COSV99496617; called by muse, mutect2, varscan2
- HOMER3 | c.1085G>A p.*362= | Silent (SNP) | VAF 409/409 reads (100%) | called by muse, mutect2, varscan2
- HSP90AB1 | c.69A>G p.Q23= | Silent (SNP) | VAF 315/316 reads (100%) | called by muse, mutect2, varscan2
- HTR2C | c.669C>T p.F223= | Silent (SNP) | VAF 435/436 reads (100%) | called by muse, mutect2, varscan2
- IGLV3-10 | c.114G>A p.R38= | Silent (SNP) | VAF 218/613 reads (36%) | catalogued as rs768059672; called by muse, mutect2
- KCNG2 | c.399C>T p.A133= | Silent (SNP) | VAF 222/223 reads (100%) | called by muse, mutect2, varscan2
- KCNN4 | c.792G>A p.K264= | Silent (SNP) | VAF 272/272 reads (100%) | called by muse, mutect2, varscan2
- KIAA1671 | c.5286C>T p.F1762= | Silent (SNP) | VAF 425/989 reads (43%) | called by muse, mutect2, varscan2
- KLHL4 | c.477C>T p.F159= | Silent (SNP) | VAF 261/261 reads (100%) | called by muse, mutect2, varscan2
- LRIF1 | c.1362C>A p.T454= | Silent (SNP) | VAF 143/143 reads (100%) | catalogued as COSV100870943; called by mutect2, varscan2
- LRP1B | c.4551G>A p.Q1517= | Silent (SNP) | VAF 122/229 reads (53%) | called by muse, mutect2, varscan2
- MAP3K19 | c.3852G>A p.G1284= | Silent (SNP) | VAF 117/245 reads (48%) | called by muse, mutect2, varscan2
- MAP3K19 | c.3102C>T p.D1034= | Silent (SNP) | VAF 77/169 reads (46%) | called by muse, mutect2, varscan2
- MED15 | c.1770C>T p.I590= (on ENST00000263205 / NM_001003891.3; = p.I550= on NM_015889.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 274/527 reads (52%) | catalogued as rs369151271; called by muse, mutect2, varscan2
- MEGF11 | c.252G>A p.R84= | Silent (SNP) | VAF 305/647 reads (47%) | catalogued as rs1313854483; called by muse, mutect2, varscan2
- MRPL32 | c.411C>T p.I137= | Silent (SNP) | VAF 291/620 reads (47%) | catalogued as COSV56239124; called by muse, mutect2, varscan2
- MUC16 | c.18390C>T p.S6130= | Silent (SNP) | VAF 335/335 reads (100%) | catalogued as rs1233429622, COSV101197562, COSV101199050; called by muse, mutect2, varscan2
- MVP | c.2583G>A p.R861= | Silent (SNP) | VAF 425/426 reads (100%) | called by muse, mutect2, varscan2
- MYO3A | c.441C>T p.I147= | Silent (SNP) | VAF 87/87 reads (100%) | catalogued as rs769644196; called by muse, mutect2, varscan2
- MYT1L | c.1155G>A p.L385= | Silent (SNP) | VAF 191/411 reads (46%) | called by muse, mutect2, varscan2
- N6AMT1 | c.507C>T p.F169= | Silent (SNP) | VAF 173/173 reads (100%) | called by muse, mutect2, varscan2
- NCKAP5 | c.2982G>A p.K994= | Silent (SNP) | VAF 134/281 reads (48%) | catalogued as rs1487157927, COSV58472233; called by muse, mutect2, varscan2
- NLRP4 | c.1617G>A p.G539= | Silent (SNP) | VAF 358/360 reads (99%) | catalogued as COSV100017101; called by muse, mutect2, varscan2
- NPAP1 | c.2631A>G p.A877= | Silent (SNP) | VAF 282/505 reads (56%) | catalogued as rs1367338924; called by muse, mutect2, varscan2
- NPC1L1 | c.1212C>T p.F404= | Silent (SNP) | VAF 364/798 reads (46%) | called by muse, mutect2, varscan2
- NRK | c.345G>A p.K115= | Silent (SNP) | VAF 234/234 reads (100%) | called by muse, mutect2, varscan2
- NUDT13 | c.666G>A p.K222= | Silent (SNP) | VAF 172/172 reads (100%) | catalogued as rs773609984; called by muse, mutect2, varscan2
- OLIG1 | c.30G>C p.V10= | Silent (SNP) | VAF 573/573 reads (100%) | called by muse, mutect2, varscan2
- OR1F1 | c.339C>T p.F113= | Silent (SNP) | VAF 365/365 reads (100%) | catalogued as COSV58960406; called by muse, mutect2, varscan2
- OR1N1 | c.624C>T p.P208= | Silent (SNP) | VAF 248/248 reads (100%) | called by muse, mutect2, varscan2
- OR2AP1 | c.201G>A p.L67= | Silent (SNP) | VAF 319/319 reads (100%) | catalogued as rs894168331; called by muse, mutect2, varscan2
- OR2T5 | c.351C>T p.F117= | Silent (SNP) | VAF 9/14 reads (64%) | called by mutect2, varscan2
- OR8H2 | c.189C>T p.F63= | Silent (SNP) | VAF 336/340 reads (99%) | catalogued as COSV57944806; called by muse, mutect2, varscan2
- PCLO | c.5097G>A p.L1699= | Silent (SNP) | VAF 267/585 reads (46%) | catalogued as rs367785097; called by muse, mutect2, varscan2
- PLEC | c.645C>T p.S215= (on ENST00000322810 / NM_201380.4; = p.S105= on NM_000445.5) | Silent (SNP) | VAF 413/811 reads (51%) | catalogued as rs781788114; called by muse, mutect2, varscan2
- PPM1E | c.1140C>G p.A380= | Silent (SNP) | VAF 204/204 reads (100%) | called by muse, mutect2, varscan2
- PURB | c.441C>T p.R147= | Silent (SNP) | VAF 436/886 reads (49%) | called by muse, mutect2, varscan2
- PXYLP1 | c.1359C>G p.V453= | Silent (SNP) | VAF 330/330 reads (100%) | called by muse, mutect2, varscan2
- RAB11FIP5 | c.1471C>T p.L491= | Silent (SNP) | VAF 228/518 reads (44%) | catalogued as rs1400994465; called by muse, mutect2, varscan2
- RAB11FIP5 | c.1470C>T p.I490= | Silent (SNP) | VAF 226/514 reads (44%) | catalogued as rs749724196; called by muse, mutect2, varscan2
- RAI1 | c.309G>A p.Q103= | Silent (SNP) | VAF 563/563 reads (100%) | called by muse, mutect2, varscan2
- RAMP3 | c.180C>T p.S60= | Silent (SNP) | VAF 234/500 reads (47%) | catalogued as rs1003173817; called by muse, mutect2, varscan2
- RGS14 | c.252C>T p.F84= | Silent (SNP) | VAF 381/381 reads (100%) | catalogued as rs1477360491; called by muse, mutect2, varscan2
- ROR2 | c.1479C>T p.F493= | Silent (SNP) | VAF 420/420 reads (100%) | catalogued as rs368196613, COSV65218463; called by muse, mutect2, varscan2
- RUFY4 | c.567G>A p.R189= | Silent (SNP) | VAF 183/356 reads (51%) | catalogued as COSV100722843, COSV60247690; called by muse, mutect2, varscan2
- RYR1 | c.4521G>A p.R1507= | Silent (SNP) | VAF 414/414 reads (100%) | catalogued as COSV62105098; called by muse, mutect2, varscan2
- SALL3 | c.2610G>A p.G870= | Silent (SNP) | VAF 552/554 reads (100%) | catalogued as COSV73306639; called by muse, mutect2, varscan2
- SCRIB | c.2454G>A p.E818= | Silent (SNP) | VAF 660/1435 reads (46%) | called by muse, mutect2, varscan2
- SGSH | c.141C>T p.T47= | Silent (SNP) | VAF 455/456 reads (100%) | called by muse, mutect2, varscan2
- SH3GL2 | c.1023C>T p.I341= | Silent (SNP) | VAF 250/250 reads (100%) | called by muse, mutect2, varscan2
- SHPK | c.231C>T p.P77= | Silent (SNP) | VAF 401/403 reads (100%) | called by muse, mutect2, varscan2
- SKOR1 | c.1359C>T p.G453= | Silent (SNP) | VAF 492/1119 reads (44%) | called by muse, mutect2, varscan2
- SLC7A4 | c.1824C>T p.F608= | Silent (SNP) | VAF 330/784 reads (42%) | catalogued as rs1276103836; called by muse, mutect2, varscan2
- SLCO1C1 | c.573C>T p.F191= | Silent (SNP) | VAF 206/478 reads (43%) | catalogued as COSV56871785, COSV56879186; called by muse, mutect2, varscan2
- SLIT1 | c.1374C>T p.P458= | Silent (SNP) | VAF 398/400 reads (100%) | called by muse, mutect2
- SP140L | c.1413G>A p.E471= | Silent (SNP) | VAF 30/123 reads (24%) | called by muse, mutect2, varscan2
- SPTBN1 | c.5412C>T p.S1804= | Silent (SNP) | VAF 138/264 reads (52%) | called by muse, mutect2, varscan2
- SSC5D | c.4320C>T p.P1440= | Silent (SNP) | VAF 509/510 reads (100%) | called by mutect2, varscan2
- TEDC1 | c.1227G>A p.K409= (on ENST00000392523 / NM_001367178.1; = p.K340= on NM_001134875.1) | Silent (SNP) | VAF 444/445 reads (100%) | called by muse, mutect2, varscan2
- THNSL2 | c.1197C>T p.Y399= | Silent (SNP) | VAF 172/349 reads (49%) | called by muse, mutect2, varscan2
- TMEM168 | c.1614C>T p.S538= | Silent (SNP) | VAF 180/387 reads (47%) | catalogued as rs752103834; called by muse, mutect2, varscan2
- TMEM53 | c.198C>T p.I66= | Silent (SNP) | VAF 197/197 reads (100%) | called by muse, mutect2, varscan2
- TMPRSS13 | c.1725C>T p.S575= | Silent (SNP) | VAF 394/394 reads (100%) | called by muse, mutect2, varscan2
- TNR | c.3201G>A p.E1067= | Silent (SNP) | VAF 467/468 reads (100%) | catalogued as rs753307143; called by muse, mutect2, varscan2
- TSPYL5 | c.243C>T p.L81= | Silent (SNP) | VAF 609/1301 reads (47%) | catalogued as rs909808475; called by muse, mutect2, varscan2
- TTN | c.66957C>T p.I22319= (on ENST00000591111; = p.I14895= on NM_003319.4) | Silent (SNP) | VAF 120/278 reads (43%) | catalogued as COSV100599747, COSV59958093; called by muse, mutect2, varscan2
- ULK4 | c.3828G>A p.*1276= | Silent (SNP) | VAF 239/239 reads (100%) | called by muse, mutect2, varscan2
- UNC45B | c.1944G>A p.Q648= | Silent (SNP) | VAF 249/249 reads (100%) | called by muse, mutect2, varscan2
- VBP1 | c.48G>A p.G16= | Silent (SNP) | VAF 404/404 reads (100%) | catalogued as rs11544264; called by muse, mutect2, varscan2
- WDR11 | c.27G>A p.K9= | Silent (SNP) | VAF 322/323 reads (100%) | called by muse, mutect2, varscan2
- WIPI2 | c.1356G>A p.R452= | Silent (SNP) | VAF 306/661 reads (46%) | catalogued as rs756801702; called by muse, mutect2, varscan2
- YIF1A | c.705C>T p.A235= | Silent (SNP) | VAF 485/486 reads (100%) | called by muse, mutect2, varscan2
- ZFHX4 | c.9870C>T p.V3290= | Silent (SNP) | VAF 311/670 reads (46%) | catalogued as COSV51467324; called by muse, mutect2, varscan2
- ZGPAT | c.222G>A p.Q74= | Silent (SNP) | VAF 807/807 reads (100%) | catalogued as rs758958907; called by muse, mutect2, varscan2
- ZNF12 | c.1032G>A p.Q344= (on ENST00000405858 / NM_016265.4; = p.Q306= on NM_006956.3) | Silent (SNP) | VAF 239/517 reads (46%) | called by muse, mutect2, varscan2
- ZNF180 | c.1980C>T p.P660= | Silent (SNP) | VAF 148/148 reads (100%) | called by muse, mutect2, varscan2
- ZNF197 | c.69C>T p.T23= | Silent (SNP) | VAF 199/199 reads (100%) | called by muse, mutect2, varscan2
- ZNF274 | c.525C>T p.P175= (on ENST00000610905; = p.P70= on NM_016324.3) | Silent (SNP) | VAF 306/307 reads (100%) | catalogued as rs1390571769, COSV100465263, COSV58763928; called by muse, mutect2, varscan2
- ZNF442 | c.585C>T p.N195= | Silent (SNP) | VAF 144/144 reads (100%) | called by muse, mutect2, varscan2
- AC092718.9 | chr16:81148187 G>A | 5'Flank (SNP) | VAF 308/308 reads (100%) | called by muse, mutect2, varscan2
- ASIC1 | c.559-3019C>T | Intron (SNP) | VAF 327/328 reads (100%) | called by muse, mutect2, varscan2
- BAD | c.*143C>T | 3'UTR (SNP) | VAF 250/250 reads (100%) | catalogued as COSV99657319; called by muse, mutect2, varscan2
- C9orf129 | n.537G>A | RNA (SNP) | VAF 377/434 reads (87%) | called by muse, mutect2, varscan2
- DNAJB5 | c.-157G>C | 5'UTR (SNP) | VAF 33/747 reads (4%) | called by muse, mutect2
- FLT4 | c.*357C>T | 3'UTR (SNP) | VAF 444/444 reads (100%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+37435G>A | Intron (SNP) | VAF 650/670 reads (97%) | called by muse, mutect2, varscan2
- LYPD6B | c.5+29846C>T | Intron (SNP) | VAF 111/238 reads (47%) | called by muse, mutect2, varscan2
- NHS | c.853-2047G>A | Intron (SNP) | VAF 302/302 reads (100%) | catalogued as rs960230379; called by muse, mutect2, varscan2
- SLC45A4 | c.*104C>T | 3'UTR (SNP) | VAF 309/653 reads (47%) | called by muse, mutect2, varscan2
- TASOR2 | c.-223dup | 5'UTR (INS) | VAF 101/143 reads (71%) | catalogued as rs1367581319; called by mutect2, pindel, varscan2
